MMRF case MMRF_1293 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/025f47c1-81bc-4b9f-95e8-661487df6451

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.4 years (21,678 days); ISS stage: II; Days to last known disease status: 1,457 days (4.0 years); Days to last follow up: 1,457 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 432 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 32 days; Days to treatment end: 432 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 916 days (2.5 years); Days to treatment end: 1,163 days (3.2 years).
   Treatment given: Therapeutic agents: Lenalidomide + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,320 days (3.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,457.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -66 (ECOG 0): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.5 mg/dL; Immunoglobulin G 31.4 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.07 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 7.9 g/dL; Glucose 6 mmol/L.
- Day 29 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.71 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.17 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 6.7 g/dL; Glucose 6.99 mmol/L.
- Day 43: M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.93 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.45 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 7.98 mmol/L.
- Day 89 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 10.5 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 4.12 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 7.76 mmol/L.
- Day 218: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 8.33 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.55 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.69 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 8.91 mmol/L.
- Day 277: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 5.22 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 8.42 mmol/L.
- Day 365 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 9.88 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 99.9 µmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 9.02 mmol/L.
- Day 481 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 9.95 g/L; Lactate Dehydrogenase 5.53 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.44 mmol/L.
- Day 568 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Immunoglobulin G 13.3 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 8.53 mmol/L.
- Day 609 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 12.5 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 8.58 mmol/L.
- Day 810 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 17.2 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.03 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 9.85 mmol/L.
- Day 916 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 16.4 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 11.1 mmol/L.
- Day 972 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 12.1 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 11.7 mmol/L.
- Day 1,063 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 13.2 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 13.9 mmol/L.
- Day 1,163 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.55 mg/dL; Immunoglobulin G 17.7 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 0.84 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 14 mmol/L.
- Day 1,288 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.52 mg/dL; Immunoglobulin G 21.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 11.1 mmol/L.
- Day 1,450 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.86 mg/dL; Immunoglobulin G 32.2 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 7.2 g/dL; Glucose 14.4 mmol/L.

Other clinical attributes
- Day -66: Weight: 82 kg; Height: 174 cm.

Biospecimens (4 samples)
- Sample MMRF_1293_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -66 days.
- Sample MMRF_1293_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 365 days (1.0 years).
- Sample MMRF_1293_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 916 days (2.5 years).
- Sample MMRF_1293_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,288 days (3.5 years).
